Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A4MT, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A4MT-02A (Recurrent Tumor).

ICD-O-3
Astrocytoma, anaplastic
C6F 9401/3
Site Supratentorial NOS
C71.0
path
① grain, temporal
lobe C71.2
9/0 4/16/13

Specimen Collected Date: [REDACTED]
Order Number: [REDACTED]
Medical Record Number: [REDACTED]
Status: F

Specimen Received Date: [REDACTED]
Ordering Provider: [REDACTED]
Facility: [REDACTED]

Accession #: [REDACTED]
Pathologist: [REDACTED]
Date of Procedure: [REDACTED]
Date Received: [REDACTED]
Submitting Physician: [REDACTED]
Location: [REDACTED]

FINAL DIAGNOSIS

A. TUMOR, EXCISION:
--WHO GRADE III GLIOMA WITH ASTROCYTIC AND OLIGODENDROGLIAL FEATURES, SEE NOTE.

Note: The specimen was sent to [REDACTED] in consultation. His diagnosis is "anaplastic astrocytoma, WHO grade III."
Within his comment he states "while there are some oligodendroglial features, the tumor overall has nuclear pleomorphism of an astrocytoma." A copy of [REDACTED] consultation report is on file in the Immunohistochemistry with antibody directed against mutant IDH-1 is reactive with the tumor.

Out By [REDACTED]

Electronically Signed

Clinical History:
left frontotemporal mass

Specimens Submitted As:

A: TUMOR

Gross Description:

Received fresh, labeled with the patient's name and number, is one pink-tan irregular soft tissue fragment measuring 2.0 x 1.5 x 0.6 cm. On section, the fragment is light tan. Submitted entirely in one cassette.

Brain malignancy - oligodendroglioma, grade II.

Recurrence

Source: NCI Genomic Data Commons file 9e618f8f-dee8-40cb-b161-5dd6c6691c6d (TCGA-FG-A4MT.592AF347-5CB0-43E7-8950-D78B9A2D670B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).